Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A82C, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A82C-01A (Primary Tumor).

Surgical Date:

Gross Description: A mass is located in left heel skin and ulcerated, with 5x3x1cm, firm, brown, black-gray surface

Microscopic Description: Epidermis is necrotic, ulcerated. Tumor is composed of sheet or trabeculae or nests of spindle or oval tumor cells with quite scant cytoplasm. Sometime the cytoplasm contains finely divided melanin pigment granulae. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are present. Tumor cells invade into fat tissue.

Diagnosis Details: Malignant melanoma

Breslow thickness: 10mm

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin, foot *non-glabrous - per TSS.*

Tumor size: 5 x 3 x 1 cm

Tumor features: Ulcerated, Pigmented, Necrotic

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 0/10 positive for metastasis (Bilateral inguinal lymph node 0/10)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Left heel, Breslow thickness: 10mm

Comments: None

*ICD-O-3
Melanoma, malignant NOS
8720/3
Site @ foot, skin C44.7
9/10/30/13*

Reviewed Initial	Date Reviewed	Signature

hw 10/23/13
10/10/13

Source: NCI Genomic Data Commons file b657eb3e-9503-4f7e-ac36-4c260d9df593 (TCGA-EB-A82C.F6E5A5AD-0C3A-4E70-82B5-C814BBAF8987.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).